Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8077, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8077-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Case ID	OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path
Report

STOMACH TISSUE
CHECKLIST

Specimen type:
Gastrectomy
Tumor site: Fundus
Tumor size: 6 x 4.5 x 1.5
cm
Tumor features: None
specified
Histologic type:
Adenocarcinoma, intestinal
type
Histologic grade:
Moderately differentiated
Tumor extent: Adjacent
structures (specify) -
Lesser omentum
Lymph nodes: 2/7 positive
for metastasis
(Intraabdominal 2/7)
Lymphatic invasion: Not
specified
Venous invasion: Not
specified
Perineural invasion: Not
specified
Margins: Not specified
Evidence of neo-adjuvant
treatment: Not specified
Additional pathologic

Laterality

Fundus

Excision date

Source: NCI Genomic Data Commons file f05299b7-b6cd-48b4-8249-cc7dd40b6396 (TCGA-BR-8077.01880B73-3EBD-4819-B500-878DEC6D39C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).